Somatic mutation profile of tumor specimen 0DLIFN from CCDI case PBBYXU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 3.8 years (1,403 days).
Specimen 0DLIFN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4f0c207-7ba4-4e4a-82b3-d00b0fd53937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIF7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d7dbdf-8a3f-403d-be0b-b0f84755700c

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2orf69 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 124/1274 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs781605495, COSV60666386; called by muse, mutect2
- FRK | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 196/636 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770056660, COSV101606673; called by mutect2, varscan2
- MUC16 | c.16829G>A p.R5610Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.199); catalogued as rs761072024, COSV67470593; called by mutect2, varscan2
- SH3TC2 | c.3457G>A p.A1153T | Missense Mutation (SNP) | VAF 104/663 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as rs778351829, COSV60468055; called by muse, mutect2, varscan2
- ASXL1 | c.3177G>A p.M1059I | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2
- DUSP22 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 32/818 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- F2RL3 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCLO | c.8444G>A p.G2815D | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC37A4 | c.1123+2T>G p.X375_splice | Splice Site (SNP) | VAF 21/483 reads (4%) | called by muse, mutect2
- SPEN | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 126/864 reads (15%) | called by muse, mutect2, varscan2
- TAS2R9 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CORO1B | c.996C>T p.C332= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as rs1223890449, COSV57055045; called by muse, mutect2, varscan2
- OPLAH | c.96C>T p.V32= | Silent (SNP) | VAF 37/496 reads (7%) | catalogued as COSV70678036; called by muse, mutect2
- HOXA2 | c.-82C>T | 5'UTR (SNP) | VAF 23/121 reads (19%) | catalogued as rs1472786614; called by muse, mutect2, varscan2
- LINC01446 | n.1816T>G | RNA (SNP) | VAF 29/410 reads (7%) | called by muse, mutect2
